Somatic mutation profile of tumor specimen TCGA-PR-A5PH-01A (aliquot TCGA-PR-A5PH-01A-11D-A35D-08) from TCGA case TCGA-PR-A5PH, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 47.5 years (17,347 days).
Specimen TCGA-PR-A5PH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69a9bf64-516d-468e-a748-8992081cdb10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PR-A5PH-10B (Blood Derived Normal), aliquot TCGA-PR-A5PH-10B-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f4fc0be-fb9d-4622-a22a-c65508d04f18

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP13A4 | c.1186A>G p.R396G | Missense Mutation (SNP) | VAF 90/233 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs761900569; called by muse, mutect2, varscan2
- DGUOK | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs977157089, COSV104383218, COSV99903696; called by muse, mutect2, varscan2
- PTPN13 | c.5944A>G p.K1982E (on ENST00000411767 / NM_080683.3; = p.K1963E on NM_006264.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs1276202973; called by muse, mutect2, varscan2
- SLC46A1 | c.1025A>G p.N342S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.482); catalogued as rs1049462297; called by muse, mutect2, varscan2
- CDKN2C | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMNA | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- OTULIN | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACTR1B | c.534C>T p.H178= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs1421383466; called by muse, mutect2, varscan2
- DOCK9 | c.2085C>T p.S695= (on ENST00000376460 / NM_001366676.2; = p.S696= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs941739290; called by muse, mutect2, varscan2
